FM case AD9195 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS.
https://portal.gdc.cancer.gov/cases/54c5a965-e3b6-4612-9c78-f05a910915bb

Female, 71.1 years: Endometrioid adenocarcinoma, NOS (ICD-O-3 8380/3) of the uterus; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
